Somatic mutation profile of tumor specimen BA3171D (aliquot aq-BA3171D) from BEATAML1.0 case 2719, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.5 years (20,280 days).
Specimen BA3171D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02ea2f16-16eb-456a-a162-758166014bcb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3359D (Solid Tissue Normal), aliquot aq-BA3359D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20fa884a-fe7e-4a6e-b0f9-b07f65ade85b

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/106 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM4 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs377004554, COSV99055663; called by muse, mutect2, varscan2
- MYOM1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375858580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPL | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs747981593; called by muse, mutect2, varscan2
- SPTBN4 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774383165; called by muse, mutect2, varscan2
- NCKAP5 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NUP205 | c.1941G>A p.L647= | Silent (SNP) | VAF 65/93 reads (70%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.420C>T p.G140= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs772558508, COSV99342884; called by muse, mutect2, varscan2
- ZNF721 | c.210A>G p.Q70= (on ENST00000338977; = p.Q82= on NM_133474.4) | Silent (SNP) | VAF 144/356 reads (40%) | catalogued as rs375285496; called by muse, mutect2, varscan2
